Somatic mutation profile of tumor specimen MMRF_1717_1_BM_CD138pos (aliquot MMRF_1717_1_BM_CD138pos_T2_KBS5U_L05833) from MMRF case MMRF_1717, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.5 years (23,560 days).
Specimen MMRF_1717_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05dfb6bf-9851-4b3b-9370-0d0c7d054cf0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1717_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1717_1_PB_Whole_C3_KBS5U_L05766; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74dd4e7e-4527-4876-bfb7-0213624c1645

The open-access MAF lists 98 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 23, Intron 14, Silent 12, 5'UTR 5, 5'Flank 4, Splice Site 3, In Frame Del 2, 3'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LZTR1 | c.436T>A p.L146M | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555927611; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 50/86 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV54354040; called by muse, mutect2, varscan2
- ADGRV1 | c.5452C>T p.L1818F | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1457228920, COSV67995405; called by muse, mutect2, varscan2
- AMMECR1 | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.599); catalogued as rs1290770764; called by muse, mutect2
- ASAP1 | c.1515+1G>C p.X505_splice | Splice Site (SNP) | VAF 11/195 reads (6%) | catalogued as COSV100728075; called by muse, mutect2
- CALML3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as rs957359416, COSV59449610; called by muse, mutect2
- CYP20A1 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100619068; called by muse, mutect2, varscan2
- DAPK2 | c.1058A>T p.E353V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV56043600; called by muse, mutect2, varscan2
- DDX17 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99061223; called by muse, mutect2, varscan2
- ERGIC2 | c.1127C>T p.T376I | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs760304122; called by muse, mutect2, varscan2
- IGHV2-70 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs566067300; called by muse, varscan2
- IGLV3-1 | c.161A>C p.Y54S | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs375251465; called by muse, mutect2, varscan2
- LCE1C | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs780385036, COSV64218273; called by muse, mutect2
- AFG1L | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ANKRD50 | c.2795T>C p.L932P | Missense Mutation (SNP) | VAF 110/158 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BPTF | c.6295C>T p.P2099S | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CACNA2D3 | c.1929A>T p.E643D | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ELAC1 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- FOXE1 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- GABRA4 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- H1-4 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- HDAC4 | c.3083_3103del p.W1028_T1035delinsS | In Frame Del (DEL) | VAF 29/72 reads (40%) | called by mutect2, pindel, varscan2
- ITGAE | c.316-2A>T p.X106_splice | Splice Site (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- LAMTOR2 | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LTBP3 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PPP1R9B | c.757C>G p.P253A | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTDSS2 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- RABGAP1 | c.1855T>G p.Y619D | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- SETD5 | c.1250_1279del p.N417_P427delinsT | In Frame Del (DEL) | VAF 32/164 reads (20%) | called by mutect2, pindel
- SH2D4B | c.224A>T p.D75V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SHMT1 | c.1282+2T>C p.X428_splice | Splice Site (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- TNRC6C | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TTLL5 | c.1777T>G p.L593V | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UBE2QL1 | c.81G>C p.W27C | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YLPM1 | c.1942G>C p.A648P | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF853 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ANOS1 | c.1239A>G p.G413= | Silent (SNP) | VAF 31/31 reads (100%) | called by muse, mutect2, varscan2
- CNTFR | c.801C>A p.I267= | Silent (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- CSMD3 | c.294A>G p.E98= | Silent (SNP) | VAF 21/27 reads (78%) | called by muse, mutect2, varscan2
- MKRN3 | c.504G>A p.L168= | Silent (SNP) | VAF 26/78 reads (33%) | called by muse, varscan2
- MROH2A | c.4971C>A p.V1657= | Silent (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- OAZ1 | c.324G>A p.T108= | Silent (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
- OR4Q3 | c.57A>G p.E19= | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- OR52M1 | c.684G>A p.V228= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs945828147; called by muse, mutect2, varscan2
- PDE3A | c.1572G>A p.S524= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs149916680, COSV62985735; called by muse, mutect2, varscan2
- RETREG1 | c.363C>A p.S121= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV60453042; called by muse, mutect2, varscan2
- SPATA16 | c.1155T>C p.T385= | Silent (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- ZNF382 | c.1221G>A p.P407= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs780590866, COSV53086148; called by muse, mutect2, varscan2
- AC068533.4 | c.564-12931C>G | Intron (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- ADAMDEC1 | c.*117T>C | 3'UTR (SNP) | VAF 43/53 reads (81%) | called by muse, mutect2, varscan2
- ATXN7 | c.*2543_*2544insT | 3'UTR (INS) | VAF 36/58 reads (62%) | called by mutect2, varscan2
- CADM2 | chr3:86068126 G>T | 3'Flank (SNP) | VAF 33/93 reads (35%) | catalogued as COSV101058991; called by muse, mutect2, varscan2
- CBLN2 | c.358-120C>A | Intron (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- CHMP6 | chr17:81004637 C>T | 3'Flank (SNP) | VAF 23/46 reads (50%) | catalogued as rs1413961732; called by muse, mutect2, varscan2
- CNOT2 | c.*14_*15insG | 3'UTR (INS) | VAF 10/48 reads (21%) | called by pindel, varscan2*
- CNOT2 | c.*91C>T | 3'UTR (SNP) | VAF 28/45 reads (62%) | called by muse, varscan2
- CXXC4 | c.*1110C>A | 3'UTR (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- DCC | c.*4380C>T | 3'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- DIXDC1 | c.656+728C>T | Intron (SNP) | VAF 120/212 reads (57%) | called by muse, varscan2
- DRD1 | c.-288G>A | 5'UTR (SNP) | VAF 19/23 reads (83%) | called by muse, mutect2, varscan2
- EFCAB2 | c.*1670C>G | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- EVX1 | chr7:27242525 C>T | 5'Flank (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- FAM189A1 | c.*1086G>A | 3'UTR (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- GRHL1 | c.*1164G>A | 3'UTR (SNP) | VAF 21/40 reads (53%) | catalogued as rs1274969232; called by muse, mutect2, varscan2
- HIKESHI | c.*50G>C | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- HPS3 | c.2293-12_2293-5del | Intron (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- HS1BP3 | c.623+573A>G | Intron (SNP) | VAF 16/47 reads (34%) | catalogued as rs918301448; called by muse, mutect2, varscan2
- IFT57 | c.*1580T>G | 3'UTR (SNP) | VAF 36/116 reads (31%) | called by muse, mutect2, varscan2
- ITGB1BP1 | c.-105C>T | 5'UTR (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- KCTD16 | c.*2633G>C | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- KDM8 | c.498+562C>T | Intron (SNP) | VAF 28/67 reads (42%) | catalogued as rs1174223651; called by muse, mutect2, varscan2
- KRT12 | c.651-55G>A | Intron (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+1026T>G | Intron (SNP) | VAF 46/79 reads (58%) | called by muse, varscan2
- MARS1 | c.109+275C>T | Intron (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- MAST3 | c.471-27A>G | Intron (SNP) | VAF 37/127 reads (29%) | called by muse, mutect2, varscan2
- MED12L | chr3:151086781 A>T | 5'Flank (SNP) | VAF 55/94 reads (59%) | called by muse, varscan2
- MIR4275 | n.19C>T | RNA (SNP) | VAF 49/152 reads (32%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851182 G>A | 5'Flank (SNP) | VAF 73/140 reads (52%) | called by muse, mutect2, varscan2
- PAFAH2 | c.*569T>A | 3'UTR (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.*1785del | 3'UTR (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- PCDH11Y | c.*3437G>C | 3'UTR (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- PRKD3 | c.427+67_427+79del | Intron (DEL) | VAF 26/55 reads (47%) | called by mutect2, pindel, varscan2
- PRR23C | c.-144C>T | 5'UTR (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- PSMD7 | c.*492G>A | 3'UTR (SNP) | VAF 18/29 reads (62%) | called by muse, mutect2, varscan2
- PTCH1 | c.3550-60dup | Intron (INS) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- PTH2R | c.*228A>G | 3'UTR (SNP) | VAF 42/76 reads (55%) | called by muse, mutect2, varscan2
- PTTG1IP | c.*1036del | 3'UTR (DEL) | VAF 26/61 reads (43%) | called by mutect2, pindel, varscan2
- SBF1 | c.5452-19A>T | Intron (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- SCN2B | c.*1652T>C | 3'UTR (SNP) | VAF 38/166 reads (23%) | called by muse, mutect2, varscan2
- SCP2 | chr1:52927181 G>C | 5'Flank (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- SRARP | c.*1032G>A | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- SYNPR | c.-183C>T | 5'UTR (SNP) | VAF 23/68 reads (34%) | catalogued as rs1391861836; called by muse, mutect2, varscan2
- TPO | c.*1179T>C | 3'UTR (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- TTC7A | c.*1955C>G | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- TXNDC12 | c.-45C>T | 5'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- ZIM2 | c.398-29A>G | Intron (SNP) | VAF 16/36 reads (44%) | catalogued as rs773135732; called by mutect2, varscan2
- ZNF391 | c.*1593T>C | 3'UTR (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
